Surgical pathology report (de-identified scan), TCGA case TCGA-GV-A3JW, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - Cleveland Clinic, specimen TCGA-GV-A3JW-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code _____

Patient Age/Sex / M

1CD-0-3

SPECIMEN SUBMITTED:

Part A: BLADDER TUMOR RIGHT, TUR

carcinoma, urothelial, NOS 8/20/3

Part B: BLADDER TUMOR DEEP, TUR

Site: bladder, NOS C67-9

fw 12/15/11

Final Diagnosis

A. BLADDER TUMOR RIGHT, TURBT:

INVASIVE POORLY DIFFERENTIATED TRANSITIONAL CELL CARCINOMA.

COMMENT: Tumor involves the muscularis propria.

B. BLADDER TUMOR DEEP, TURBT:

INVASIVE POORLY DIFFERENTIATED TRANSITIONAL CELL CARCINOMA INVOLVING MUSCULAR PROPRIA.

A] 307; B] 307

Diagnosis Comment:

URINARY BLADDER SYNOPTIC REPORT

PROCEDURE: TURBT

HISTOLOGIC TYPE: Transitional cell

ASSOCIATED EPITHELIAL LESIONS: None

HISTOLOGIC GRADE: III

ADEQUACY OF MATERIAL FOR DETERMINING MUSCULARIS PROPRIA INVASION: Muscularis propria

detrusor muscle present.

LYMPHVASCULAR INVASION: Not identified.

MICROSCOPIC EXTENT OF TUMOR: Tumor invades muscularis propria.

Clinical Diagnosis:

Bladder CA

Gross Description:

A. Received in fixative are multiple segments of pink-grey tissue which aggregate to 3 x 2.5 cm. The specimen is filtered and entirely submitted in two cassettes.

B. Received in fixative are multiple pink-grey tissue fragments aggregating to 2 x 2 cm. The specimen is entirely submitted in one cassette.

Source: NCI Genomic Data Commons file a19258e8-b6b3-4b1b-8b4a-5bfdea7341eb (TCGA-GV-A3JW.AC922A7D-2261-4322-99B5-BA845CC77C85.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).